Somatic mutation profile of tumor specimen TCGA-D8-A27W-01A (aliquot TCGA-D8-A27W-01A-11D-A16D-09) from TCGA case TCGA-D8-A27W, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 55.2 years (20,173 days).
Specimen TCGA-D8-A27W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db4853d8-d85a-4d88-bba8-c61655ff98ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A27W-10A (Blood Derived Normal), aliquot TCGA-D8-A27W-10A-01D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75f41158-1efe-48b1-80f7-0ad8b6466da5

The open-access MAF lists 34 somatic variants for this specimen: 29 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 4, Nonsense Mutation 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGTPBP1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs773782970, COSV100429845, COSV61268696; called by muse, mutect2, varscan2
- AL031777.2 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious, low confidence (0.05); catalogued as COSV100587264, COSV61912013, COSV61912148; called by muse, mutect2
- ASAP2 | c.626A>G p.K209R | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV55627514; called by muse, mutect2, varscan2
- CARMIL1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs555687744, COSV61513796; called by muse, mutect2, varscan2
- CCKAR | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.356); catalogued as COSV55160045, COSV55164469; called by muse, mutect2, varscan2
- CENPW | c.241-1G>A p.X81_splice | Splice Site (SNP) | VAF 13/42 reads (31%) | catalogued as COSV64176727; called by muse, mutect2, varscan2
- CFAP97 | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99703518; called by muse, mutect2, varscan2
- DIAPH1 | c.1273G>T p.E425* | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99527082; called by muse, mutect2
- DYDC1 | c.496T>C p.F166L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100943841; called by muse, mutect2
- FBXO34 | c.98T>C p.V33A | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58253354; called by muse, mutect2, varscan2
- HLX | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs1406405125, COSV100854532; called by muse, mutect2
- IGFBP4 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1167453383, COSV54096634; called by muse, mutect2, varscan2
- KCNAB1 | c.1162G>A p.A388T (on ENST00000490337 / NM_172160.3; = p.A377T on NM_003471.3) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1219671348, COSV56741419; called by muse, mutect2, varscan2
- KIF4B | c.2732A>G p.E911G | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV70527882; called by muse, mutect2, varscan2
- LIG4 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs574912936, COSV100800017; called by mutect2, varscan2
- MBNL1 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV99221057; called by muse, mutect2, varscan2
- MDGA1 | c.1023C>G p.I341M | Missense Mutation (SNP) | VAF 50/57 reads (88%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); catalogued as COSV51791824; called by muse, mutect2, varscan2
- MYLK4 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs768060086, COSV51138292; called by mutect2, varscan2
- NCBP1 | c.1325A>G p.E442G | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV100912649; called by muse, mutect2
- NCKAP1 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.869); catalogued as COSV100719946; called by muse, mutect2
- NEXMIF | c.4346G>A p.R1449H | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778760434, COSV50022011, COSV50029019; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NXPH1 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs368219961; called by muse, mutect2, varscan2
- PLSCR2 | c.599C>T p.P200L (on ENST00000497985 / NM_001199978.1; = p.P127L on NM_020359.2) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.106); catalogued as COSV100367852, COSV60859619; called by muse, mutect2, varscan2
- POU4F2 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs747030570, COSV55582913; called by muse, mutect2, varscan2
- RASGEF1C | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs774116646, COSV63177600; called by muse, mutect2, varscan2
- RPA3 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as COSV56187219, COSV56187412; called by muse, mutect2, varscan2
- SARDH | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100061092, COSV53832404; called by muse, mutect2
- ZNF721 | c.1145G>A p.C382Y (on ENST00000338977; = p.C394Y on NM_133474.4) | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as rs1179299667, COSV59089273; called by muse, mutect2, varscan2
- KASH5 | c.447C>T p.G149= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as rs1415432739, COSV101483486; called by muse, mutect2
- NGF | c.96C>A p.I32= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV101049635; called by muse, mutect2
- SEMA6D | c.168G>A p.R56= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV60372947; called by muse, mutect2, varscan2
- TSHZ2 | c.2715C>T p.Y905= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as COSV61586891; called by muse, mutect2, varscan2
- SHANK2 | c.1854-48G>C | Intron (SNP) | VAF 15/48 reads (31%) | catalogued as COSV53586225; called by muse, mutect2, varscan2
